Somatic mutation profile of tumor specimen TARGET-10-PARHSD-09A (aliquot TARGET-10-PARHSD-09A-01D) from TARGET case TARGET-10-PARHSD, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.9 years (1,425 days).
Specimen TARGET-10-PARHSD-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 174c1219-7b38-4dc6-847e-904017260124.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARHSD-10A (Blood Derived Normal), aliquot TARGET-10-PARHSD-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0fdb6acb-1fda-4de3-ac6b-cfa297f11648

The open-access MAF lists 18 somatic variants for this specimen: 8 protein-altering or splice-affecting, 5 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 5, 5'Flank 2, RNA 1, 3'UTR 1, In Frame Ins 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 30/48 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS17 | c.862C>T p.R288* | Nonsense Mutation (SNP) | VAF 14/32 reads (44%) | catalogued as rs773895033; called by muse, mutect2, varscan2
- NELL1 | c.1432G>A p.D478N | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as rs544001655, COSV54244136, COSV54248983; called by muse, mutect2, varscan2
- PRX | c.1373C>T p.A458V | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV52528009; called by muse, mutect2, varscan2
- TMEM87B | c.952A>T p.T318S | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as COSV51717338; called by muse, mutect2, varscan2
- AK7 | c.481_495dup p.S161_D165dup | In Frame Ins (INS) | VAF 26/63 reads (41%) | called by mutect2, varscan2
- BLNK | c.312A>C p.E104D | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.075); called by muse, varscan2
- SIGLEC6 | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.183); called by muse, mutect2
- CACNA1E | c.3096G>A p.Q1032= | Silent (SNP) | VAF 34/121 reads (28%) | called by muse, mutect2, varscan2
- GRIN2A | c.2196C>T p.A732= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as rs748323416, COSV100411448; called by muse, mutect2, varscan2
- MAP2 | c.3480A>T p.L1160= | Silent (SNP) | VAF 56/139 reads (40%) | called by muse, mutect2, varscan2
- MELTF | c.447G>A p.E149= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs775162735; called by muse, varscan2
- NRXN3 | c.1383C>T p.S461= | Silent (SNP) | VAF 37/138 reads (27%) | catalogued as rs1048663441; called by muse, mutect2, varscan2
- AC022517.1 | chr19:5174081 G>A | 5'Flank (SNP) | VAF 17/66 reads (26%) | catalogued as rs751332776; called by muse, mutect2, varscan2
- CD34 | chr1:207911239 C>T | 5'Flank (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
- CPT1C | c.2133+19G>A | Intron (SNP) | VAF 20/48 reads (42%) | catalogued as rs757536361; called by muse, mutect2, varscan2
- KRT8P11 | n.1059G>A | RNA (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2, varscan2
- TIGD3 | c.*19C>T | 3'UTR (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2, varscan2
